Somatic mutation profile of tumor specimen TARGET-20-PASYDA-09A (aliquot TARGET-20-PASYDA-09A-01D) from TARGET case TARGET-20-PASYDA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.9 years (5,089 days).
Specimen TARGET-20-PASYDA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fa6177d-aef0-4347-868e-a7311b2518d0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASYDA-14A (Bone Marrow Normal), aliquot TARGET-20-PASYDA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/991db032-386b-49b4-a583-fc5847b62ae0

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Splice Site 1, Frame Shift Ins 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WT1 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 96/249 reads (39%) | catalogued as rs121907909, CM971596, COSV60066326; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 27/69 reads (39%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- MACF1 | c.17473-2A>G p.X5825_splice (on ENST00000372915; = p.X3867_splice on NM_012090.5) | Splice Site (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- ALDH2 | c.-13C>T | 5'UTR (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
